Somatic mutation profile of tumor specimen TARGET-10-PARDVD-09A (aliquot TARGET-10-PARDVD-09A-01D) from TARGET case TARGET-10-PARDVD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.5 years (4,187 days).
Specimen TARGET-10-PARDVD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ea9e205-68cf-40c2-a19d-265a2aa74283.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDVD-10A (Blood Derived Normal), aliquot TARGET-10-PARDVD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b82fea2b-184f-4806-876a-7e0a56d9c6d3

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, Intron 3, Frame Shift Del 2, 5'Flank 1, 5'UTR 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30B | c.584del p.N195Mfs*26 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | catalogued as rs1207049839; called by mutect2, pindel, varscan2
- DOCK5 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.738); catalogued as rs572079060; called by muse, mutect2, varscan2
- PANX3 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766674566, COSV99421918; called by muse, mutect2
- PTPN23 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs780958960; called by mutect2, varscan2
- RASGEF1B | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52335566, COSV52338288; called by muse, mutect2
- SERTAD2 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as rs1312722769; called by muse, mutect2, varscan2
- UNC13C | c.5530G>A p.V1844I | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs377334158; called by muse, mutect2, varscan2
- BSN | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CSMD3 | c.3934G>T p.G1312C (on ENST00000297405 / NM_001363185.1; = p.G1208C on NM_052900.3) | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- DUSP1 | c.129_132del p.V44Tfs*105 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, pindel, varscan2
- FGFR1OP2 | c.227T>C p.I76T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- GPR50 | c.187+1G>A p.X63_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- MACROD2 | c.89A>T p.Y30F | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- MNT | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PIGQ | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2
- RAD50 | c.3563T>A p.M1188K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RUNX1T1 | c.397C>A p.L133M (on ENST00000265814 / NM_001198628.1; = p.L106M on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC5A8 | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMURF2 | c.343T>A p.L115M | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS33A | c.636_637insGGCCGG p.E212_F213insGR | In Frame Ins (INS) | VAF 21/65 reads (32%) | called by mutect2, pindel, varscan2
- ADAM11 | c.1716T>C p.N572= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs377581567; called by muse, mutect2, varscan2
- HMCN1 | c.4239G>A p.G1413= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs1243303441; called by muse, mutect2, varscan2
- TNKS | c.3630C>T p.A1210= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs373127636; called by muse, mutect2, varscan2
- CLEC1B | c.545+63C>G | Intron (SNP) | VAF 12/57 reads (21%) | catalogued as COSV53724819; called by muse, varscan2
- CLEC1B | c.439-159C>T | Intron (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- KLHDC8A | c.-254G>A | 5'UTR (SNP) | VAF 17/37 reads (46%) | catalogued as rs558150763; called by muse, mutect2, varscan2
- PPP1R36 | c.183-2860G>A | Intron (SNP) | VAF 15/43 reads (35%) | catalogued as rs752989677; called by muse, mutect2, varscan2
- ZNF687 | chr1:151280017 A>T | 5'Flank (SNP) | VAF 5/9 reads (56%) | called by muse, varscan2
